Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HR, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HR-01A (Primary Tumor).

Synoptic translated report

Site : Right lung inferior lobe

☒ Central ☐ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 3.5 x 2.5 x 2.0 cm

Visceral pleural invasion: ☐ Yes ☒ No ☐ NA

Chest wall invasion : ☐ Yes ☒ No ☐ NA

Histological diagnosis : Poorly differentiated basaloid squamous cell carcinoma

Node status : N1 (2/28)

TNM : pT2a pN1 (2/28) G3 R0

ICD-O-3
Carcinoma, squamous cell
basaloid 8083/3
Site: B Lung, lower lobe C34.3
JW 2/1/13

Pathologist signature:

Date:

Case #	124/13	Yes	No
H&A Discrepancy			☒
First Metastatic History	DMF-OK R/LW	☒	☒
Diagnosis, synchronous Primary Metastasis			

Source: NCI Genomic Data Commons file fd6f6c3d-3c13-489a-8366-eaccc78608a9 (TCGA-NC-A5HR.CB0090E7-0335-454E-BAFA-D2F8CBB4F131.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).